Surgical pathology report (de-identified scan), TCGA case TCGA-HC-7745, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-7745-01A (Primary Tumor).

[page 1 of 2]
Result type:
Result date:
Result status:
Result title:
Performed by:
Verified by:
Encounter info:

*** Final Report ***

Clinical History

Prostate cancer

Specimen

#1 Prostate
#2 Right pelvic lymph nodes
#3 Left pelvic lymph nodes

Gross Examination

#1 Received fresh and labeled prostate, is a 35 gram, 4.0 cm (right to left) X 3.7 cm (apex to base) X 3.5 cm (anterior to posterior) prostate with attached right and left seminal vesicles (2.5 x 1.2 x 0.8 cm, 3.0 x 2.0 x 0.8 cm, respectively). There are portions of attached right and left vasa deferentia (each 0.5 cm long). Also present within the specimen container there is a 2.5 x 1.5 x up to 0.7 cm aggregate of three irregular fragments of tubular rubbery, grey tan tissue. The right half of the prostate is inked black and the left half is inked blue. The prostate is serially sectioned from apex to base to demonstrate a 1.5 cm ill-defined focal firm area of pale tan discoloration within the mid aspect of the left posterior prostate, coming to within 0.1 cm of the blue inked outer surface. The parenchyma otherwise consists of tan, rubbery glistening parenchyma with a moderate amount of periurethral nodularity. There are no additional abnormalities identified.

A total of thirty-four sections are submitted in fifteen cassettes "A - O". Block summary: "A", right apex longitudinally sectioned; "B", left apex longitudinally sectioned; "C", right bladder neck longitudinally sectioned; "D", left bladder neck longitudinally sectioned; "E-G", right posterior prostate, from apex to base respectively; "H-J", left posterior prostate, from apex to base respectively; "K", right lateral prostate; "L", left lateral prostate; "M", anterior prostate; "N", right seminal vesicle and prostate, including right vas; "O", left seminal vesicle and prostate, including left vas. Following explicit written consent of the patient, tissue is taken for the Cancer Genome Atlas Project. [REDACTED]

#2 Labeled right pelvic lymph node, is a 3.2 x 1.0 x 0.8 cm portion of tan yellow fibroadipose tissue. Within the tissue there is a 0.8 cm lymph node candidate. The candidate is bisected and submitted as two sections in one cassette.

Printed by:
Printed on:

Page 1 of 2
(Continued)

[page 2 of 2]
#3 Labeled left pelvic lymph node, is a 4.0 x 2.5 x 1.0 cm aggregate of multiple irregular fragments of tan yellow fibroadipose tissue. Within the tissue there are two lymph node candidates, 0.4 and 2.5 cm in greatest dimension. The candidates are submitted as five sections in three: "A-C". Block summary: "A", one candidate; "B,C", larger candidate, sectioned.

OR Consultation

#1 PROSTATE, RADICAL PROSTATECTOMY: TISSUE TRIAGE FOR

Signature Line

Signed by:
ELECTRONIC SIGNATURE

Microscopic Examination

#1-#3 Microscopic examination performed.

Comment

Portions of this case have been reviewed in consultation with one additional departmental pathologist.

Final Diagnosis

#1 PROSTATE GLAND: PROSTATIC ADENOCARCINOMA.
GLEASON SCORE: 4+3=7.
TUMOR SIZE: AT LEAST 2.0 X 1.0 CM (AS MEASURED ON GLASS SLIDE "I").
PERCENT PROSTATE INVOLVEMENT, ESTIMATE: 25% OF EXAMINED SECTIONS.
TUMOR LOCATION: BILATERAL.
EXTRAPROSTATIC EXTENSION: MULTIFOCAL.
SURGICAL MARGIN STATUS: NEGATIVE.
SEMINAL VESICLE AND VASA DEFERENTIA STATUS: BILATERAL INVOLVEMENT
BY CARCINOMA.
LYMPHATIC (SMALL VESSEL) INVASION: ABSENT.
VENOUS (LARGE VESSEL) INVASION: ABSENT.
#2 RIGHT PELVIC LYMPH NODE: BENIGN LYMPH NODE.
#3 LEFT PELVIC LYMPH NODES: BENIGN LYMPH NODES (X 2).

PATHOLOGIC STAGE (TNM CLASSIFICATION): pT3b pN0.

Ordering Provider

Ordering Physician:

Printed by:
Printed on:

Source: NCI Genomic Data Commons file 8b292846-6000-4e68-9a7c-10cb3d7ace31 (TCGA-HC-7745.4A65A2D9-6007-4FF2-9711-46351F540367.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).